Gene-level copy-number profile of tumor specimen MP2PRT-PAVWAG-TMP1-A from MP2PRT case MP2PRT-PAVWAG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,945 days).
Specimen MP2PRT-PAVWAG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eabfe37a-0a37-47af-8ac7-c2d47e8603c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVWAG-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/3321a645-ad27-4029-af40-395a7d26dc8c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 141; copy number 1: 4,038; copy number 2: 53,112; copy number 3: 1,608.

Homozygous deletions (total copy number 0; autosomes only): 141 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,078,010–89,100,361, 3 genes (within-gene range 0–1): IGKV2-14, IGKV3-15, IGKV1-16.
- chr2:89,128,724–89,135,257, 2 genes (within-gene range 0–1): IGKV2-18, IGKV2-19.
- chr7:38,257,879–38,318,861, 8 genes (within-gene range 0–2): TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr14:105,672,308–106,538,344, 125 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,592,676–106,601,792, 3 genes (within-gene range 0–1): IGHV3-53, IGHVII-53-1, IGHV3-54.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,182. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
